Somatic mutation profile of tumor specimen CDDP-ABK0-TTP1-A (aliquot CDDP-ABK0-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABK0, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62 years.
Specimen CDDP-ABK0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a076872-1468-4105-bc1f-5f9c00e5f444.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABK0-NB1-A (Blood Derived Normal), aliquot CDDP-ABK0-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b92ac27-c3c0-4fd0-bb2f-20760d135828

The open-access MAF lists 396 somatic variants for this specimen: 268 protein-altering or splice-affecting, 73 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 227, Silent 73, Intron 23, Nonsense Mutation 18, 5'UTR 8, RNA 8, 5'Flank 8, 3'UTR 7, Frame Shift Del 7, Splice Site 6, Frame Shift Ins 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, varscan2
- STK11 | c.465-2A>T p.X155_splice | Splice Site (SNP) | VAF 48/85 reads (56%) | hotspot (GDC flag); catalogued as CS012224, COSV58824418, COSV58826632, COSV58828073; called by muse, mutect2, varscan2
- ABCA2 | c.1811A>T p.K604M (on ENST00000614293; = p.K574M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV55801039; called by muse, mutect2, varscan2
- ABCC11 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156933, COSV62323009; called by muse, mutect2, varscan2
- ACAN | c.5296A>T p.S1766C | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61360157; called by muse, mutect2, varscan2
- ACVR1C | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV54646062; called by muse, mutect2, varscan2
- ADAMTS2 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51077696; called by muse, mutect2, varscan2
- ADGRG2 | c.2942C>A p.T981N (on ENST00000379869 / NM_001079858.3; = p.T978N on NM_005756.4) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs1482138759, COSV61339053; called by muse, mutect2, varscan2
- ADGRV1 | c.13315C>G p.Q4439E | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV101315671; called by muse, mutect2
- AHNAK2 | c.12177C>G p.F4059L | Missense Mutation (SNP) | VAF 80/502 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as rs1484399400; called by muse, varscan2
- ANKRD53 | c.1583C>G p.T528S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.005); catalogued as COSV55537299; called by muse, varscan2
- ANO4 | c.1058G>A p.W353* (on ENST00000392977 / NM_001286615.2; = p.W318* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 50/174 reads (29%) | catalogued as COSV54595361; called by muse, mutect2, varscan2
- APLP1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.668); catalogued as rs1224573406, COSV55707503; called by muse, mutect2
- BBX | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57884289; called by muse, mutect2, varscan2
- BOD1L1 | c.5863G>A p.E1955K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50012801; called by muse, mutect2
- BRWD3 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64745141; called by muse, mutect2, varscan2
- BTNL3 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376492558; called by muse, mutect2
- CAAP1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV100445352, COSV61700704; called by muse, mutect2
- CACYBP | c.686G>C p.*229Sext*11 | Nonstop Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as COSV62880208; called by muse, mutect2
- CALB1 | c.333T>A p.D111E | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55367479; called by muse, mutect2, varscan2
- CAPN15 | c.2810C>T p.S937L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1327934673; called by muse, mutect2, varscan2
- CBLB | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 132/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51426454; called by muse, mutect2, varscan2
- CCDC138 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.515); catalogued as rs1253390323, COSV54566988; called by muse, mutect2, varscan2
- CCDC168 | c.10231A>T p.K3411* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as COSV59421905; called by muse, mutect2, varscan2
- CCNL1 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV55816910; called by muse, varscan2
- CDH6 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs867559623, COSV54067477; called by muse, mutect2
- CDK12 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as COSV71000473, COSV71001049; called by muse, mutect2
- CDKN1B | c.402del p.T135Lfs*10 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | catalogued as COSV57431701; called by mutect2, pindel, varscan2
- CELF2 | c.1306G>A p.D436N (on ENST00000416382 / NM_001025077.3; = p.D449N on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59973684; called by muse, mutect2, varscan2
- CENPJ | c.2482A>G p.N828D | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV67883417; called by muse, mutect2, varscan2
- CFAP46 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs957189721, COSV63951047; called by muse, mutect2, varscan2
- CFAP58 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV57212097; called by muse, mutect2, varscan2
- CIC | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 151/255 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV50568753; called by muse, mutect2, varscan2
- CLDN4 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782109277, COSV52895789; called by muse, mutect2, varscan2
- CLIC6 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1296868842, COSV62447657; called by muse, varscan2
- CLIP1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419623714, COSV56801603; called by muse, mutect2, varscan2
- CMKLR1 | c.605C>G p.S202W (on ENST00000312143 / NM_001142344.2; = p.S200W on NM_004072.3) | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV56438149; called by muse, mutect2, varscan2
- CNTN4 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV68570884; called by muse, mutect2, varscan2
- CNTNAP4 | c.1637C>G p.S546* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100272189; called by muse, mutect2
- COG7 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs781068033, COSV56150303; called by muse, mutect2, varscan2
- COL7A1 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.085); catalogued as rs372786023; called by muse, mutect2
- COL9A1 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV57883358; called by muse, mutect2, varscan2
- CR1 | c.3799C>A p.H1267N | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100887387; called by muse, mutect2
- CREBBP | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV52116689, COSV52121576; called by muse, mutect2
- CSMD1 | c.5773A>T p.S1925C (on ENST00000520002; = p.S1924C on NM_033225.6) | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59321934; called by muse, mutect2, varscan2
- CSMD1 | c.624C>A p.C208* | Nonsense Mutation (SNP) | VAF 47/90 reads (52%) | catalogued as COSV68203262; called by muse, mutect2, varscan2
- CSMD3 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 107/203 reads (53%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as rs553446393, COSV52176529; called by muse, mutect2, varscan2
- CTAG2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV55994730; called by muse, varscan2
- CTNNA2 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100561543, COSV58151794; called by muse, mutect2
- CUBN | c.4282A>C p.S1428R | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV64715376; called by muse, mutect2, varscan2
- DCBLD2 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1468750533, COSV58789436; called by muse, varscan2
- DENND2B | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1258045916, COSV58203528; called by muse, mutect2, varscan2
- DEPDC5 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430793856, COSV56691978; called by muse, mutect2, varscan2
- DHH | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV57201971; called by muse, mutect2, varscan2
- DLGAP2 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV70097981; called by muse, mutect2, varscan2
- DNAH9 | c.4364C>T p.P1455L | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV52348811; called by muse, mutect2, varscan2
- DNAJC25 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.475); catalogued as COSV57956703; called by muse, mutect2, varscan2
- DOP1B | c.2521T>C p.S841P | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV67693333; called by muse, mutect2, varscan2
- DSE | c.2460T>G p.D820E | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as COSV59063832; called by muse, mutect2, varscan2
- DSE | c.2461G>T p.A821S | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.005); catalogued as COSV59063847; called by muse, mutect2, varscan2
- DYNC1H1 | c.5555A>G p.D1852G | Missense Mutation (SNP) | VAF 167/350 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV64136839; called by muse, mutect2, varscan2
- ENO4 | c.1421C>T p.S474F (on ENST00000622726; = p.S471F on NM_001242699.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); catalogued as COSV58004791; called by muse, mutect2, varscan2
- EPB42 | c.1232C>A p.T411K (on ENST00000441366 / NM_001114134.2; = p.T441K on NM_000119.3) | Missense Mutation (SNP) | VAF 152/372 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV55749596; called by muse, mutect2, varscan2
- EPHB1 | c.1168C>G p.R390G | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as COSV67658326, COSV67661315, COSV67672652; called by muse, mutect2, varscan2
- FAM135B | c.3212T>A p.L1071* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV52703951, COSV52723738; called by muse, mutect2, varscan2
- FAM83B | c.1212G>T p.R404S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV60921948; called by muse, mutect2, varscan2
- FBXO30 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV99395347; called by muse, mutect2
- FERD3L | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1406197403, COSV51762194, COSV51762637; called by muse, mutect2, varscan2
- FRAS1 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53609234; called by muse, mutect2, varscan2
- FREM2 | c.9210T>G p.S3070R | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54837273; called by muse, mutect2, varscan2
- FSIP1 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63224800; called by muse, mutect2, varscan2
- GAPVD1 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV52922005, COSV52922883; called by muse, mutect2, varscan2
- GJC1 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765128025, COSV57911247; called by muse, mutect2, varscan2
- GP2 | c.839A>C p.Q280P (on ENST00000381362 / NM_001007240.3; = p.Q277P on NM_001502.4) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56894011; called by muse, mutect2, varscan2
- GPR156 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs768056878, COSV59938182; called by muse, mutect2, varscan2
- GRID2IP | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70692469; called by muse, mutect2, varscan2
- GRIK2 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59773988; called by muse, mutect2
- GUCY2C | c.2971G>C p.G991R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53790057; called by muse, mutect2, varscan2
- HBQ1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs1173842291, COSV52265654; called by muse, mutect2, varscan2
- HCN1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.253); catalogued as COSV57507887, COSV57521104; called by muse, mutect2
- HCN1 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 167/648 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57509762, COSV57536048; called by muse, mutect2, varscan2
- HTR1A | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.852); catalogued as COSV60500742; called by muse, mutect2, varscan2
- IBTK | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV60392785; called by muse, mutect2, varscan2
- IGSF9 | c.1255G>A p.A419T (on ENST00000368094 / NM_001135050.2; = p.A403T on NM_020789.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.336); catalogued as rs1240901003; called by muse, mutect2, varscan2
- ILK | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54449542; called by muse, mutect2, varscan2
- IRS4 | c.2510T>C p.L837P | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV64533772; called by muse, mutect2, varscan2
- ISL2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1297225863; called by muse, mutect2
- ITGAD | c.2067C>G p.F689L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV66757399, COSV66757939; called by muse, mutect2, varscan2
- KCNJ4 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57857052, COSV57858126; called by muse, mutect2, varscan2
- KCNQ2 | c.1693A>C p.M565L (on ENST00000359125 / NM_172107.4; = p.M537L on NM_004518.6) | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV60544638; called by muse, mutect2, varscan2
- KEAP1 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV50261803; called by muse, mutect2, varscan2
- KRT26 | c.664A>C p.K222Q | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV104408969, COSV59414093; called by muse, mutect2, varscan2
- LAMA2 | c.7456G>A p.E2486K | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV70346802; called by muse, mutect2, varscan2
- LIPI | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs781312488, COSV60711304; called by muse, mutect2, varscan2
- LOXHD1 | c.2956G>A p.V986M | Missense Mutation (SNP) | VAF 136/285 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1030067220, COSV56064009; called by muse, mutect2, varscan2
- LRRC7 | c.1096G>A p.A366T (on ENST00000651989 / NM_001370785.2; = p.A333T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1326288620, COSV50454621; called by muse, mutect2, varscan2
- LRRC8D | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61579137; called by muse, mutect2, varscan2
- MAMDC2 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65858030; called by muse, mutect2, varscan2
- MARCHF9 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.54); catalogued as rs373196172; called by muse, mutect2
- MASP1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs202134503; called by muse, mutect2, varscan2
- MDN1 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1031121421, COSV65521385; called by muse, mutect2, varscan2
- MDN1 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65521390; called by muse, mutect2, varscan2
- MED25 | c.1975G>T p.G659W | Missense Mutation (SNP) | VAF 104/176 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV57204355; called by muse, mutect2, varscan2
- MIDN | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs1315330602; called by muse, mutect2
- MKI67 | c.8347A>C p.S2783R | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV64074259; called by muse, mutect2, varscan2
- MKRN3 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58809822; called by muse, mutect2, varscan2
- MOV10 | c.1725C>G p.I575M | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV62491338; called by muse, mutect2, varscan2
- MRGPRX2 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1432558814; called by muse, mutect2
- MRGPRX4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753184956, COSV58590490, COSV58591004; called by muse, mutect2, varscan2
- MS4A12 | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50014455; called by muse, mutect2, varscan2
- MTMR11 | c.1510C>T p.P504S (on ENST00000439741 / NM_001145862.2; = p.P432S on NM_181873.3) | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs377606749; called by muse, mutect2
- MTRR | c.2153G>T p.R718L (on ENST00000264668; = p.R691L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/398 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1320146714, COSV52943695; called by muse, mutect2, varscan2
- MXRA5 | c.4531C>A p.P1511T | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV54234613; called by muse, mutect2, varscan2
- MYH15 | c.3922G>T p.A1308S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.074); catalogued as rs368413041; called by muse, mutect2, varscan2
- MYH7 | c.4423C>T p.R1475C | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139646545, CM050711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.3452C>G p.S1151* | Nonsense Mutation (SNP) | VAF 54/286 reads (19%) | catalogued as rs1296176095, COSV73244867; called by muse, mutect2, varscan2
- NCOA5 | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 85/458 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.258); catalogued as COSV51644306; called by muse, mutect2, varscan2
- NCOA7 | c.2235G>C p.K745N | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57655255; called by muse, mutect2, varscan2
- NEGR1 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV60831895, COSV60844308; called by muse, mutect2, varscan2
- NEU4 | c.721G>A p.A241T (on ENST00000391969 / NM_001167602.3; = p.A253T on NM_080741.4) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57990302; called by muse, mutect2, varscan2
- NOC3L | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs753022530, COSV64929660; called by muse, mutect2, varscan2
- OR1N2 | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65460590; called by mutect2, varscan2
- OR1Q1 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV52917586; called by muse, mutect2, varscan2
- OR5T3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs769725086, COSV57379541, COSV57382979; called by muse, mutect2, varscan2
- OR8H3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57908838; called by muse, mutect2
- OR9A4 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV71885415; called by muse, mutect2, varscan2
- ORC5 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs762714914, COSV52398553; called by muse, mutect2, varscan2
- PADI6 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs548655558, COSV61884598; called by muse, mutect2, varscan2
- PALM | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs765205567, COSV52768118; called by muse, mutect2, varscan2
- PCDH10 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as COSV52093617; called by muse, mutect2, varscan2
- PCDH15 | c.2967A>G p.I989M | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV57307977; called by muse, mutect2, varscan2
- PCDHB7 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 44/587 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV99175319; called by muse, mutect2
- PCDHGC5 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52745397; called by muse, mutect2, varscan2
- PDE1B | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs558733078, COSV54492626; called by muse, mutect2, varscan2
- PDGFRA | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as COSV57266918; called by muse, mutect2
- PIP5K1C | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs984426151, COSV58950169; called by muse, mutect2
- PLAGL1 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52786609; called by muse, mutect2, varscan2
- POLD1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101486903; called by muse, mutect2, varscan2
- PPFIA1 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs748263753, COSV54136686; called by muse, mutect2, varscan2
- PPFIA2 | c.3109T>A p.Y1037N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61031697; called by muse, mutect2, varscan2
- PPP2R3A | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.145); catalogued as rs1244413714, COSV53863630; called by muse, mutect2, varscan2
- PRAMEF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.033); catalogued as rs764271433, COSV52440767; called by muse, mutect2, varscan2
- PRPF4 | c.346G>A p.E116K (on ENST00000374198 / NM_001322267.2; = p.E117K on NM_004697.5) | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs372954091; called by muse, mutect2, varscan2
- PRUNE2 | c.3226C>A p.Q1076K | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.273); catalogued as COSV65041390; called by muse, mutect2, varscan2
- PTCHD4 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV59783828; called by muse, mutect2, varscan2
- PTCHD4 | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.901); catalogued as COSV59783839; called by muse, mutect2, varscan2
- PTPN12 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV50358319; called by muse, mutect2, varscan2
- RAB32 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV62249130, COSV62249134; called by muse, varscan2
- RAB7A | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 103/357 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV54041559; called by muse, mutect2, varscan2
- RAD50 | c.3883C>T p.Q1295* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | catalogued as rs1330031894, COSV54751219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM4B | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV59496517; called by muse, mutect2, varscan2
- RHBDF1 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV51955435; called by muse, mutect2, varscan2
- RP1L1 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 78/549 reads (14%) | catalogued as COSV66754798; called by muse, mutect2, varscan2
- RTF1 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); catalogued as COSV67477650, COSV67477723; called by muse, mutect2, varscan2
- RTL1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1203522201; called by muse, mutect2
- SCARF1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs1411828804; called by muse, mutect2
- SEMA3D | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as COSV52392975; called by muse, mutect2, varscan2
- SEMA5A | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV66789979; called by muse, mutect2
- SERPINA7 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59665747; called by muse, mutect2, varscan2
- SFXN5 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs764726890, COSV55586789, COSV99730074; called by muse, mutect2, varscan2
- SKAP2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV61723492, COSV61725933; called by muse, mutect2, varscan2
- SLC22A12 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs753490462, COSV60572106; called by muse, mutect2, varscan2
- SLC22A2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs750937051, COSV65265768; called by muse, mutect2
- SLC4A9 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 46/341 reads (13%) | catalogued as COSV50189556, COSV99139712; called by muse, mutect2, varscan2
- SLC5A8 | c.1385T>C p.I462T | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV73310642; called by muse, mutect2, varscan2
- SMOC2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs765267119, COSV62433766; called by muse, mutect2
- SMPD1 | c.1515C>G p.N505K | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV54968029; called by muse, mutect2, varscan2
- SNRNP200 | c.6163C>T p.L2055F | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs772983143; called by muse, mutect2
- SNRNP200 | c.5208C>G p.F1736L | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60489915; called by muse, mutect2
- SOWAHD | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104416591, COSV59649634; called by muse, mutect2, varscan2
- SPAG16 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1267091621, COSV56970151; called by muse, mutect2, varscan2
- SYNE2 | c.1411A>C p.N471H | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV59950615; called by muse, mutect2, varscan2
- SYNE2 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59974101; called by muse, mutect2, varscan2
- SYTL3 | c.1741G>A p.G581S (on ENST00000611299 / NM_001242394.1; = p.G513S on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.115); catalogued as COSV51910227; called by muse, mutect2, varscan2
- TAFA4 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs746528039, COSV55134313; called by muse, mutect2, varscan2
- TENM1 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV64424457, COSV64440000; called by muse, mutect2, varscan2
- TENM3 | c.2546G>T p.S849I | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV69307578; called by muse, mutect2, varscan2
- TEX13C | c.1208A>C p.N403T | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs772010798; called by muse, mutect2, varscan2
- TMED3 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); catalogued as rs946373152, COSV69696277; called by muse, mutect2, varscan2
- TMTC1 | c.604C>T p.P202S (on ENST00000539277 / NM_001193451.2; = p.P94S on NM_175861.3) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV55493389; called by muse, mutect2, varscan2
- TNS4 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); catalogued as COSV54183607; called by muse, mutect2
- TP53 | c.179del p.P60Qfs*63 | Frame Shift Del (DEL) | VAF 86/211 reads (41%) | catalogued as COSV52908942, COSV53348579, COSV53683260; called by mutect2, pindel, varscan2
- TSPAN14 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV59368066; called by muse, mutect2, varscan2
- TTN | c.94228G>A p.E31410K (on ENST00000591111; = p.E23986K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | PolyPhen benign (0.169); catalogued as rs144319649, COSV59894575; ClinVar: uncertain significance; called by muse, mutect2
- UNC13C | c.1659T>G p.F553L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV52864546; called by muse, mutect2, varscan2
- UNC5A | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.95); catalogued as COSV52839874; called by muse, mutect2, varscan2
- USP13 | c.1564A>T p.R522W | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55865607; called by muse, mutect2, varscan2
- USP40 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV52480635; called by muse, mutect2, varscan2
- VSIG10L | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); catalogued as rs1442002314; called by muse, mutect2, varscan2
- VSTM4 | c.690C>G p.S230R | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60526300; called by muse, mutect2, varscan2
- WDR86 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs767757447, COSV57839893; called by muse, mutect2, varscan2
- XIRP2 | c.5173G>T p.E1725* (on ENST00000628543; = p.E1900* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | catalogued as COSV54699256; called by muse, mutect2, varscan2
- ZBTB46 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs751567417, COSV55509907; called by muse, mutect2
- ZDHHC8 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV57708984; called by muse, varscan2
- ZNF140 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60579597; called by muse, mutect2
- ZNF180 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777499069, COSV55421157; called by muse, mutect2, varscan2
- ABCB6 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ABCC8 | c.1332+7G>A | Splice Region (SNP) | VAF 35/221 reads (16%) | called by muse, mutect2, varscan2
- AC138647.1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); called by muse, varscan2
- ACACA | c.4078G>T p.G1360W | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSL1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- BCL11B | c.1615G>C p.E539Q (on ENST00000357195 / NM_001282237.2; = p.E468Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- BCL11B | c.1614G>T p.E538D (on ENST00000357195 / NM_001282237.2; = p.E467D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C16orf96 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C21orf91 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- CASR | c.1827del p.S610Afs*11 (on ENST00000490131; = p.S687Afs*11 on NM_000388.4) | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- CCDC88B | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CCNT2 | c.159-1G>T p.X53_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- CLGN | c.420-2A>G p.X140_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- COL24A1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DLL3 | c.225_236del p.P76_L79del | In Frame Del (DEL) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- DNAJC13 | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 10/185 reads (5%) | called by muse, mutect2
- DOCK9 | c.6112A>T p.K2038* (on ENST00000376460 / NM_001366676.2; = p.K2039* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- EFCAB14 | c.327T>G p.F109L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- ETAA1 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171A1 | c.418+1G>T p.X140_splice | Splice Site (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- FAM47B | c.648del p.K217Rfs*133 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- FOS | c.490dup p.T164Nfs*12 | Frame Shift Ins (INS) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- FSCB | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- FSIP2 | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- GJA1 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLRX2 | c.404C>G p.T135S (on ENST00000367439 / NM_197962.3; = p.T136S on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- GPATCH8 | c.2049dup p.S684Ifs*7 | Frame Shift Ins (INS) | VAF 107/335 reads (32%) | called by mutect2, pindel, varscan2
- HBG1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 49/460 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- IFITM3 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFITM3 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- IFNA16 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- IKZF5 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); called by muse, mutect2
- KIAA1671 | c.3153G>T p.L1051F | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- LIG4 | c.1899G>C p.K633N | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2
- LIPT2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- LRCH4 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- MCOLN2 | c.1128T>A p.D376E | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2
- MGAM | c.4869G>T p.M1623I | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MIEF1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2
- MS4A6A | c.364A>C p.I122L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MS4A6A | c.363C>A p.S121R | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NRXN3 | c.1339del p.D447Tfs*37 (on ENST00000335750 / NM_001330195.2; = p.D74Tfs*37 on NM_004796.6) | Frame Shift Del (DEL) | VAF 31/193 reads (16%) | called by mutect2, pindel, varscan2
- NSA2 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OR10Z1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGR | c.1635G>C p.L545= | Splice Region (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PRAMEF15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/436 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRL | c.193_204+12del p.X65_splice | Splice Site (DEL) | VAF 55/237 reads (23%) | called by mutect2, pindel, varscan2
- RBM48 | c.433dup p.T145Nfs*3 | Frame Shift Ins (INS) | VAF 7/81 reads (9%) | called by mutect2, pindel
- RICTOR | c.1145G>C p.R382T | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.125); called by muse, mutect2
- RNF148 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.73); called by muse, mutect2
- RPL15 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- SART1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- SDR39U1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); called by muse, mutect2
- SLC25A32 | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- SLC26A6 | c.2066T>A p.L689Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX31 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 182/411 reads (44%) | called by muse, mutect2, varscan2
- SPEG | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTAN1 | c.2810C>A p.S937* | Nonsense Mutation (SNP) | VAF 36/530 reads (7%) | called by muse, mutect2
- SRRM2 | c.4820del p.K1607Sfs*91 | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- STIM2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUCLG2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TACC2 | c.8458C>G p.Q2820E (on ENST00000334433; = p.Q898E on NM_006997.4) | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TEP1 | c.7606A>T p.S2536C | Missense Mutation (SNP) | VAF 172/414 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TRBV23-1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TRIM64B | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- TTL | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.39938G>C p.R13313T (on ENST00000591111; = p.R5889T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | PolyPhen benign (0.007); called by muse, mutect2
- USP38 | c.1051-3_1051delinsTTTT p.X351_splice | Splice Site (ONP) | VAF 6/74 reads (8%) | called by mutect2*, pindel
- VPS13A | c.100+6G>A | Splice Region (SNP) | VAF 74/246 reads (30%) | called by muse, mutect2, varscan2
- VPS37A | c.1040del p.N347Ifs*13 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- WDR24 | c.1067G>C p.G356A (on ENST00000248142; = p.G226A on NM_032259.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.669); called by muse, mutect2
- ABCA12 | c.6225C>T p.L2075= (on ENST00000272895 / NM_173076.3; = p.L1757= on NM_015657.3) | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- AGPAT1 | c.87C>T p.S29= | Silent (SNP) | VAF 136/401 reads (34%) | called by muse, mutect2, varscan2
- AL441992.2 | c.549G>T p.P183= | Silent (SNP) | VAF 85/369 reads (23%) | catalogued as COSV56913650; called by muse, mutect2, varscan2
- AP2A2 | c.1404C>T p.V468= | Silent (SNP) | VAF 76/234 reads (32%) | catalogued as rs764637759, COSV59960250; called by muse, mutect2, varscan2
- ATP13A1 | c.2055C>T p.V685= | Silent (SNP) | VAF 51/94 reads (54%) | catalogued as COSV52285674; called by muse, mutect2, varscan2
- ATP13A2 | c.2845C>T p.L949= | Silent (SNP) | VAF 180/469 reads (38%) | catalogued as COSV58700429; called by muse, mutect2, varscan2
- CAMKK2 | c.1449C>T p.T483= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs200794906, COSV61218526; called by muse, mutect2, varscan2
- CASP1 | c.831G>A p.P277= (on ENST00000436863 / NM_033292.4; = p.P256= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as rs1456744063, COSV62056501; called by muse, mutect2, varscan2
- CATIP | c.702C>A p.V234= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV56822641; called by muse, mutect2, varscan2
- CCDC88B | c.1851G>T p.P617= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV57266123; called by muse, mutect2, varscan2
- CDCA8 | c.132G>A p.Q44= | Silent (SNP) | VAF 29/167 reads (17%) | catalogued as COSV59238794; called by muse, mutect2, varscan2
- CLRN2 | c.528C>T p.F176= | Silent (SNP) | VAF 42/431 reads (10%) | catalogued as COSV71825204; called by muse, mutect2, varscan2
- CNNM4 | c.612C>T p.L204= | Silent (SNP) | VAF 23/293 reads (8%) | called by muse, mutect2
- COLGALT1 | c.1776G>A p.Q592= | Silent (SNP) | VAF 10/348 reads (3%) | called by muse, mutect2
- CSNK1E | c.1119G>A p.E373= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- DDX24 | c.1302G>A p.L434= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- DNAH5 | c.12603C>T p.F4201= | Silent (SNP) | VAF 65/574 reads (11%) | catalogued as rs758897089, COSV54223789; called by muse, mutect2, varscan2
- DUXA | c.261G>A p.Q87= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV73729670; called by muse, mutect2, varscan2
- ERFE | c.228C>A p.V76= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV60138177; called by muse, mutect2, varscan2
- EYS | c.2361T>A p.T787= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV65491915; called by muse, mutect2, varscan2
- FAT4 | c.14951G>A p.*4984= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, varscan2
- FBXO7 | c.726C>T p.L242= | Silent (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- FBXW11 | c.1557C>T p.F519= | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- GEMIN4 | c.2487G>A p.S829= | Silent (SNP) | VAF 23/397 reads (6%) | catalogued as rs751977516, COSV56745309; called by muse, mutect2
- IGF1R | c.102G>T p.G34= | Silent (SNP) | VAF 45/292 reads (15%) | catalogued as COSV51286284; called by muse, mutect2, varscan2
- IL1RAPL1 | c.39T>A p.A13= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as COSV56260238; called by muse, mutect2, varscan2
- IQSEC3 | c.696C>T p.G232= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- KIF26B | c.3558C>T p.D1186= | Silent (SNP) | VAF 51/293 reads (17%) | catalogued as rs542994340, COSV63641290; called by muse, mutect2, varscan2
- KLHDC7A | c.1314G>T p.V438= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as COSV68769732; called by muse, mutect2, varscan2
- KRT16 | c.447C>A p.I149= | Silent (SNP) | VAF 65/782 reads (8%) | catalogued as COSV56969173; called by muse, mutect2
- LOXHD1 | c.6576G>A p.Q2192= (on ENST00000642948; = p.Q2130= on NM_144612.7) | Silent (SNP) | VAF 34/652 reads (5%) | called by muse, mutect2
- MED23 | c.2811C>T p.L937= | Silent (SNP) | VAF 36/306 reads (12%) | catalogued as rs765058820, COSV63432424; ClinVar: likely benign; called by muse, mutect2, varscan2
- MFGE8 | c.489C>T p.S163= | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- MOV10L1 | c.1059C>T p.S353= | Silent (SNP) | VAF 73/259 reads (28%) | catalogued as rs762879678, COSV53170897; called by muse, mutect2, varscan2
- MRGPRX4 | c.618C>A p.S206= | Silent (SNP) | VAF 84/220 reads (38%) | catalogued as COSV58590501; called by muse, mutect2, varscan2
- MSH3 | c.2499C>T p.C833= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- NCOA4 | c.417C>T p.L139= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- NDST4 | c.1524C>A p.I508= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52112022, COSV52119354; called by muse, varscan2
- NELL1 | c.1758C>A p.T586= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV54263130; called by muse, mutect2, varscan2
- NPR3 | c.1371G>A p.L457= | Silent (SNP) | VAF 9/168 reads (5%) | catalogued as COSV54087544; called by muse, mutect2
- OASL | c.372G>A p.E124= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as COSV57478245; called by muse, mutect2, varscan2
- OR14A16 | c.183G>A p.L61= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- OR4C6 | c.333C>A p.I111= | Silent (SNP) | VAF 40/195 reads (21%) | catalogued as COSV58603912, COSV58606218; called by muse, mutect2, varscan2
- OR4K17 | c.60C>A p.S20= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV59648013, COSV59649186; called by muse, mutect2, varscan2
- OR52A5 | c.765C>T p.Y255= | Silent (SNP) | VAF 68/210 reads (32%) | catalogued as COSV56615199; called by muse, mutect2, varscan2
- OR6K6 | c.297C>T p.I99= (on ENST00000368144; = p.I75= on NM_001005184.1) | Silent (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- OVCH1 | c.2307T>C p.C769= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV58962704; called by muse, varscan2
- PAK1 | c.1350G>T p.L450= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs1315228621, COSV53696389; called by muse, mutect2, varscan2
- PDE2A | c.1509C>G p.L503= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, varscan2
- PHF8 | c.1470C>T p.I490= (on ENST00000357988 / NM_001184896.1; = p.I454= on NM_015107.3) | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- PKHD1 | c.7437C>T p.L2479= | Silent (SNP) | VAF 9/296 reads (3%) | catalogued as COSV61885002; called by muse, mutect2
- PLXDC2 | c.750C>T p.L250= | Silent (SNP) | VAF 17/241 reads (7%) | catalogued as COSV65901423; called by muse, mutect2
- POM121L2 | c.2301C>T p.S767= | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as rs950826241, COSV66276145; called by muse, mutect2
- POTEC | c.393G>A p.P131= | Silent (SNP) | VAF 53/607 reads (9%) | catalogued as rs1472359294, COSV62803607; called by muse, mutect2
- R3HDML | c.96C>A p.A32= | Silent (SNP) | VAF 76/223 reads (34%) | catalogued as COSV53835946; called by muse, mutect2, varscan2
- RAP1GDS1 | c.672T>A p.I224= (on ENST00000408927 / NM_001100427.2; = p.I225= on NM_021159.5) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV52787095; called by muse, mutect2, varscan2
- RBMXL2 | c.1035A>G p.R345= | Silent (SNP) | VAF 72/272 reads (26%) | catalogued as rs1198539356, COSV60979988; called by muse, mutect2, varscan2
- REEP4 | c.645A>G p.R215= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV57941899; called by muse, mutect2, varscan2
- RNF122 | c.72G>A p.S24= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs755028263, COSV56359262; called by mutect2, varscan2
- SGIP1 | c.204T>C p.Y68= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV52768368; called by muse, mutect2, varscan2
- STK32B | c.1095C>T p.F365= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TEX13C | c.240G>A p.A80= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs771615609; called by muse, mutect2, varscan2
- TGM7 | c.1887C>A p.T629= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV71772791; called by muse, mutect2
- THBD | c.108C>T p.F36= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV65702786; called by muse, mutect2
- TLN2 | c.576G>A p.T192= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs1338733842, COSV60890239; called by muse, mutect2
- TRABD2B | c.414C>A p.P138= | Silent (SNP) | VAF 38/227 reads (17%) | catalogued as rs557048813, COSV71109253; called by muse, mutect2, varscan2
- UBR1 | c.3345A>G p.V1115= | Silent (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- UBR2 | c.36C>T p.I12= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1212131276; called by muse, mutect2
- WDR24 | c.375G>T p.L125= (on ENST00000248142; = p.L63= on NM_032259.4) | Silent (SNP) | VAF 13/361 reads (4%) | called by muse, mutect2
- WIPI2 | c.462G>T p.T154= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV56588827, COSV99993412; called by muse, mutect2, varscan2
- ZNF208 | c.3828T>A p.T1276= | Silent (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- ZNF479 | c.1098G>A p.S366= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as rs372917800; called by mutect2, varscan2
- ZSCAN31 | c.987G>A p.G329= | Silent (SNP) | VAF 80/239 reads (33%) | catalogued as COSV60180844; called by muse, mutect2, varscan2
- ACAD9 | c.*27G>A | 3'UTR (SNP) | VAF 32/498 reads (6%) | catalogued as rs756131819; called by muse, mutect2
- ACTB | c.-27-17G>T | Intron (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668246 C>T | 5'Flank (SNP) | VAF 10/269 reads (4%) | called by muse, mutect2
- AP000769.5 | chr11:65498909 G>A | 5'Flank (SNP) | VAF 28/136 reads (21%) | called by muse, varscan2
- AP000769.5 | chr11:65499660 G>T | 5'Flank (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500178 G>T | 5'Flank (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500626 G>T | 5'Flank (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- BMS1P15 | n.479G>A | RNA (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
- CHID1 | chr11:914561 C>T | 5'Flank (SNP) | VAF 9/103 reads (9%) | catalogued as rs1338375993; called by muse, mutect2
- CHRNA4 | c.*3150C>A | 3'UTR (SNP) | VAF 70/149 reads (47%) | called by muse, mutect2, varscan2
- CPNE9 | c.110-9C>A | Intron (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- DENND2B | c.2721-583G>T | Intron (SNP) | VAF 24/152 reads (16%) | catalogued as rs1391096691; called by muse, mutect2, varscan2
- DGKA | c.64+13G>T | Intron (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- DLL4 | c.*44A>T | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, varscan2
- EYS | c.1767-7106C>A | Intron (SNP) | VAF 14/64 reads (22%) | catalogued as rs532184533; called by mutect2, varscan2
- FBXO24 | c.39+57G>T | Intron (SNP) | VAF 90/300 reads (30%) | called by muse, mutect2, varscan2
- GRAMD2B | c.203+759C>G | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as COSV53507397; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1876A>T | RNA (SNP) | VAF 147/676 reads (22%) | called by muse, mutect2, varscan2
- HOOK3 | c.1620+39C>T | Intron (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- IGKV1-27 | c.-11C>T | 5'UTR (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- IGSF1 | c.1718-23C>A | Intron (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- INO80C | c.157-6833C>T | Intron (SNP) | VAF 10/15 reads (67%) | catalogued as rs757853582; called by muse, mutect2, varscan2
- LHCGR | c.-38A>G | 5'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- LINC00632 | n.58G>A | RNA (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- LINC01556 | n.101G>A | RNA (SNP) | VAF 5/49 reads (10%) | catalogued as rs572930024; called by muse, mutect2, varscan2
- LRP5L | n.555C>T | RNA (SNP) | VAF 48/242 reads (20%) | catalogued as rs747847029, COSV68602112; called by muse, mutect2, varscan2
- MAP7D3 | chrX:136256306 C>A | 5'Flank (SNP) | VAF 23/42 reads (55%) | catalogued as COSV60170913; called by muse, mutect2, varscan2
- MASP1 | c.1304-5078G>A | Intron (SNP) | VAF 29/241 reads (12%) | catalogued as rs756129126; called by muse, mutect2, varscan2
- MXRA8 | c.*264G>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- MYO19 | c.1905+107T>A | Intron (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- NPIPB14P | n.118C>T | RNA (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- OR7E5P | n.548C>G | RNA (SNP) | VAF 36/227 reads (16%) | catalogued as rs778744999; called by muse, mutect2, varscan2
- OXR1 | c.223+62092C>T | Intron (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- PAX6 | c.682+20T>A | Intron (SNP) | VAF 62/200 reads (31%) | catalogued as rs571505590; called by muse, mutect2, varscan2
- PDCD6 | c.163+3289G>A | Intron (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- PHF23 | c.-23G>A | 5'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- PIN1 | c.58+1420G>C | Intron (SNP) | VAF 10/97 reads (10%) | catalogued as rs1174018182; called by muse, mutect2
- PLA2G15 | c.404-18C>T | Intron (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- POTEC | c.1126+1514G>C | Intron (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- PPP1R1B | chr17:39622102 C>A | 5'Flank (SNP) | VAF 98/235 reads (42%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.-33C>T | 5'UTR (SNP) | VAF 13/139 reads (9%) | catalogued as COSV52793567; called by muse, mutect2
- RAPH1 | c.732+12485G>A | Intron (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- SLC18B1 | c.-19C>T | 5'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44334C>A | Intron (SNP) | VAF 14/95 reads (15%) | catalogued as COSV67443083, COSV67443703; called by muse, mutect2, varscan2
- SP140 | c.-8C>A | 5'UTR (SNP) | VAF 22/268 reads (8%) | catalogued as COSV59447639; called by muse, mutect2
- SSPOP | n.9471G>T | RNA (SNP) | VAF 47/152 reads (31%) | catalogued as COSV65129821; called by muse, mutect2, varscan2
- ST3GAL5 | c.319-84G>C | Intron (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- SUPT20HL2 | c.-669G>C | 5'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- TARBP1 | c.-6C>T | 5'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as rs775258898; called by muse, mutect2, varscan2
- USP19 | c.606+178C>T | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as rs745970218, COSV59733351; called by muse, mutect2, varscan2
- VSX1 | chr20:25071413 G>T | 3'Flank (SNP) | VAF 20/148 reads (14%) | called by muse, varscan2
- XIAP | c.*5646dup | 3'UTR (INS) | VAF 17/54 reads (31%) | catalogued as rs767212056; called by mutect2, varscan2
- XIRP2 | c.*518T>C | 3'UTR (SNP) | VAF 62/192 reads (32%) | catalogued as COSV54699262; called by muse, mutect2
- XIRP2 | c.*520T>A | 3'UTR (SNP) | VAF 62/192 reads (32%) | catalogued as COSV54699274; called by muse, mutect2
- ZEB2 | c.73+5720C>T | Intron (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
